Somatic mutation profile of tumor specimen TCGA-IN-A6RI-01A (aliquot TCGA-IN-A6RI-01A-11D-A32N-08) from TCGA case TCGA-IN-A6RI, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 46.0 years (16,788 days).
Specimen TCGA-IN-A6RI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f0a6c25-d844-42c0-af1c-c1c86a91d2c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IN-A6RI-10A (Blood Derived Normal), aliquot TCGA-IN-A6RI-10A-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/972b4d06-b18f-48f2-a802-e598024bb6b3

The open-access MAF lists 112 somatic variants for this specimen: 81 protein-altering or splice-affecting, 27 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 27, Nonsense Mutation 5, Translation Start Site 2, Intron 2, RNA 1, Splice Site 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 30/47 reads (64%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCE1 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV99668573; called by muse, mutect2, varscan2
- ACSS3 | c.237A>C p.K79N | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV99698842; called by muse, mutect2, varscan2
- ADGRL2 | c.4243G>T p.A1415S (on ENST00000370717 / NM_001366005.1; = p.A1359S on NM_012302.4) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs770815631, COSV99589180; called by muse, mutect2, varscan2
- AMPH | c.126T>A p.Y42* | Nonsense Mutation (SNP) | VAF 30/84 reads (36%) | catalogued as COSV100342142; called by muse, mutect2, varscan2
- AMY2B | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 129/596 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as COSV100796310; called by muse, mutect2, varscan2
- ARID5B | c.1004G>A p.R335K | Missense Mutation (SNP) | VAF 51/97 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV54423256; called by muse, mutect2, varscan2
- ATP1B2 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100006889; called by muse, mutect2, varscan2
- BTBD3 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV54780136, COSV99655884; called by muse, mutect2
- CAPSL | c.231A>T p.K77N | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs1431719578, COSV101274264; called by muse, mutect2, varscan2
- CCDC88C | c.4161A>C p.K1387N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101105638; called by muse, mutect2, varscan2
- CDH11 | c.1937A>G p.E646G | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.963); catalogued as COSV99218417; called by muse, mutect2, varscan2
- CDH23 | c.3547C>T p.H1183Y | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as COSV99821021; called by mutect2, varscan2
- COL19A1 | c.2428G>A p.G810R | Missense Mutation (SNP) | VAF 74/205 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778932497, COSV59590285; called by muse, mutect2, varscan2
- CSE1L | c.137T>C p.L46P | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99522017; called by muse, mutect2, varscan2
- CTNNA2 | c.2738A>C p.K913T (on ENST00000402739 / NM_001282597.3; = p.K865T on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/219 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100560708, COSV100562362; called by muse, mutect2, varscan2
- DHX16 | c.872A>G p.K291R | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV100905202; called by muse, mutect2, varscan2
- DNMT1 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV61577509; called by muse, mutect2, varscan2
- DYNC1LI1 | c.901G>C p.V301L | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as COSV99818154; called by muse, mutect2, varscan2
- EBF3 | c.1417G>A p.V473I (on ENST00000355311 / NM_001375392.1; = p.V464I on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs150680609; called by muse, mutect2, varscan2
- EPHA7 | c.1574A>C p.N525T | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV100993715; called by muse, mutect2, varscan2
- FRAS1 | c.10268C>T p.P3423L | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs891439423, COSV53629620; called by muse, mutect2, varscan2
- GIMAP6 | c.233C>T p.T78I | Missense Mutation (SNP) | VAF 99/191 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.285); catalogued as COSV100188236; called by muse, mutect2, varscan2
- GRM1 | c.668A>C p.N223T | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV99266270; called by muse, mutect2, varscan2
- HGD | c.791A>G p.N264S | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1469714335, COSV99380962; called by muse, mutect2, varscan2
- KCNA5 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs866085758, COSV99363903; called by muse, mutect2
- KCNS3 | c.128A>G p.K43R | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100411221; called by muse, mutect2, varscan2
- KIF12 | c.1366C>T p.R456C (on ENST00000640217; = p.R318C on NM_138424.1) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs774477975, COSV65117601; called by mutect2, varscan2
- KIF2B | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 37/115 reads (32%) | catalogued as rs779266250, COSV52128868, COSV99275302; called by muse, mutect2, varscan2
- KIF2C | c.1084C>T p.L362F | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100945721; called by muse, mutect2
- LAMC1 | c.4595T>C p.L1532P | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.388); catalogued as COSV99279603; called by muse, mutect2
- LAT2 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs369438020; called by muse, mutect2
- LCE1D | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 9/110 reads (8%) | PolyPhen possibly damaging (0.658); catalogued as COSV100405889; called by muse, mutect2
- LPA | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 91/270 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100307020, COSV60302026; called by muse, mutect2, varscan2
- LRP12 | c.1721T>G p.V574G | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99407747; called by muse, mutect2, varscan2
- LTK | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as COSV55491620; called by muse, mutect2, varscan2
- MAML2 | c.1162G>A p.G388S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as COSV101594113; called by muse, mutect2, varscan2
- MED12L | c.2934C>A p.F978L | Missense Mutation (SNP) | VAF 96/229 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV99853192; called by muse, mutect2, varscan2
- MKRN3 | c.92A>C p.D31A | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV100091143; called by muse, mutect2, varscan2
- MYH1 | c.3749A>T p.E1250V | Missense Mutation (SNP) | VAF 47/71 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99875956; called by muse, mutect2, varscan2
- MYH2 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99820148; called by muse, mutect2, varscan2
- NALCN | c.3749T>C p.F1250S | Missense Mutation (SNP) | VAF 77/115 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV99215246; called by muse, mutect2, varscan2
- NAV3 | c.2834A>G p.K945R | Missense Mutation (SNP) | VAF 77/208 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV99891043; called by muse, mutect2, varscan2
- NBN | c.1642A>G p.N548D | Missense Mutation (SNP) | VAF 77/175 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs772234785, COSV99619465; called by muse, mutect2, varscan2
- NOL9 | c.1918G>A p.V640I | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.04); catalogued as rs757747589, COSV100891460; called by muse, mutect2, varscan2
- NOVA1 | c.707T>G p.L236R | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV57473964; called by muse, mutect2, varscan2
- NTHL1 | c.260G>A p.W87* (on ENST00000219066; = p.W79* on NM_002528.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 56/181 reads (31%) | catalogued as COSV99526322; called by muse, mutect2, varscan2
- OR1A1 | c.529T>G p.F177V | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58404831; called by muse, mutect2, varscan2
- OR2G3 | c.266A>C p.K89T | Missense Mutation (SNP) | VAF 97/324 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100180610; called by muse, mutect2, varscan2
- OR4A16 | c.190T>A p.L64M | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100125225, COSV59042593, COSV59042620; called by muse, mutect2
- OR4P4 | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 53/77 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV100111739; called by muse, mutect2, varscan2
- PBXIP1 | c.414G>C p.W138C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.855); catalogued as COSV100870084; called by muse, mutect2, varscan2
- PCDHGA12 | c.1465T>C p.Y489H | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99340174; called by muse, mutect2
- POSTN | c.1087C>A p.Q363K | Missense Mutation (SNP) | VAF 47/70 reads (67%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs777895150, COSV101123331; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1406G>A p.G469E (on ENST00000352766; = p.G390E on NM_181334.5) | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.125); catalogued as COSV100424271; called by muse, mutect2
- RIMS2 | c.1342T>G p.L448V (on ENST00000666250 / NM_001348490.2; = p.L256V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.034); catalogued as COSV51669105, COSV51676746; called by muse, mutect2
- RIMS2 | c.4681C>T p.P1561S (on ENST00000666250 / NM_001348490.2; = p.P1132S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99169604; called by muse, mutect2
- SCN2A | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs387906686, CM106922, COSV51834971; ClinVar: pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- SLC44A5 | c.398T>A p.L133H | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.261); catalogued as COSV100902016; called by muse, mutect2
- SLC49A3 | c.982G>A p.V328M (on ENST00000404286 / NM_001294341.2; = p.V327M on NM_032219.4) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.835); catalogued as rs756207017, COSV100448450; called by muse, mutect2, varscan2
- SLC9C2 | c.1610G>A p.R537Q | Missense Mutation (SNP) | VAF 61/218 reads (28%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.548); catalogued as rs745902865, COSV62947207; called by muse, mutect2, varscan2
- SLITRK6 | c.2480T>G p.L827* | Nonsense Mutation (SNP) | VAF 68/101 reads (67%) | catalogued as COSV101233236; called by muse, mutect2, varscan2
- SMARCA2 | c.2654A>G p.Q885R | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100570988; called by muse, mutect2, varscan2
- SMYD2 | c.1221+1G>T p.X407_splice | Splice Site (SNP) | VAF 34/97 reads (35%) | catalogued as COSV100873210; called by muse, mutect2, varscan2
- SOHLH2 | c.254A>C p.K85T | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV58520560, COSV58522859; called by muse, mutect2, varscan2
- SPANXN1 | c.100T>G p.L34V | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.68); catalogued as COSV100979279, COSV65121824, COSV65122226; called by muse, mutect2
- TENM4 | c.5761G>C p.G1921R | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99574746; called by muse, mutect2, varscan2
- TFAP4 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as COSV99200055; called by muse, mutect2, varscan2
- TRIM67 | c.1247G>A p.R416K | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV100792126; called by muse, mutect2, varscan2
- TTN | c.97876A>G p.K32626E (on ENST00000591111; = p.K25202E on NM_003319.4) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | PolyPhen benign (0.053); catalogued as COSV60434711; called by muse, mutect2, varscan2
- TTN | c.2428C>T p.R810C (on ENST00000591111; = p.R764C on NM_003319.4) | Missense Mutation (SNP) | VAF 35/65 reads (54%) | PolyPhen benign (0.011); catalogued as rs375132408; called by muse, mutect2, varscan2
- UBASH3B | c.1760T>C p.L587P | Missense Mutation (SNP) | VAF 32/448 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99417778, COSV99419354; called by muse, mutect2
- WDR72 | c.1955C>T p.S652L | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1340122319, COSV100854471; called by muse, mutect2, varscan2
- WDR93 | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 343/624 reads (55%) | SIFT tolerated (0.62); PolyPhen benign (0.173); catalogued as COSV99175617; called by muse, mutect2, varscan2
- XPOT | c.2044G>A p.D682N | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV100225533; called by muse, mutect2, varscan2
- ZNF2 | c.1053C>A p.D351E (on ENST00000611147 / NM_001291605.2; = p.D338E on NM_021088.4) | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99728478, COSV99728773; called by muse, mutect2, varscan2
- ZNF213 | c.1224G>C p.K408N | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV101205980, COSV67727432; called by muse, mutect2, varscan2
- ZNF460 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV100828081, COSV64416490; called by muse, mutect2
- ZNF71 | c.1294C>T p.H432Y | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100045933; called by muse, mutect2, varscan2
- MGME1 | c.482_491del p.G161Afs*30 | Frame Shift Del (DEL) | VAF 15/155 reads (10%) | called by mutect2, pindel
- MRC1 | c.2899A>T p.R967* | Nonsense Mutation (SNP) | VAF 11/179 reads (6%) | called by muse, mutect2
- ADCY10 | c.4005T>C p.H1335= | Silent (SNP) | VAF 105/344 reads (31%) | catalogued as COSV100896855; called by muse, mutect2, varscan2
- ANO2 | c.1842T>C p.T614= (on ENST00000356134 / NM_001278597.3; = p.T618= on NM_001278596.3) | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV100500969, COSV59013968; called by muse, mutect2, varscan2
- ANO6 | c.2544G>A p.V848= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV100263195; called by muse, mutect2, varscan2
- BICC1 | c.519G>A p.R173= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as rs764573345, COSV100874851; called by muse, mutect2, varscan2
- CADPS | c.3960C>T p.N1320= | Silent (SNP) | VAF 37/119 reads (31%) | catalogued as rs1265089784, COSV99338285; called by muse, mutect2, varscan2
- CCDC178 | c.381T>G p.T127= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV100284911; called by muse, mutect2, varscan2
- CDH3 | c.1221C>T p.Y407= | Silent (SNP) | VAF 187/318 reads (59%) | catalogued as rs368241091; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRACD | c.3051G>A p.S1017= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs1165019084, COSV99948341; called by muse, mutect2, varscan2
- CRISPLD1 | c.759A>G p.E253= | Silent (SNP) | VAF 42/163 reads (26%) | catalogued as COSV100082012; called by muse, mutect2, varscan2
- DCDC1 | c.4882A>C p.R1628= (on ENST00000597505 / NM_001367979.1; = p.R735= on NM_020869.3) | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as COSV100360532; called by muse, mutect2, varscan2
- DUSP15 | c.684G>A p.P228= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs905766500, COSV99639590, COSV99639768; called by muse, mutect2, varscan2
- GPX5 | c.540T>C p.R180= | Silent (SNP) | VAF 65/172 reads (38%) | catalogued as rs772777598, COSV101297262; called by muse, mutect2, varscan2
- KALRN | c.3441A>G p.Q1147= | Silent (SNP) | VAF 64/182 reads (35%) | catalogued as COSV99564374; called by muse, mutect2, varscan2
- LUZP2 | c.450C>T p.H150= | Silent (SNP) | VAF 13/170 reads (8%) | catalogued as rs367630511, COSV100419359; called by muse, mutect2
- MARCHF7 | c.714G>A p.T238= | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as rs200191640; called by muse, mutect2, varscan2
- MNDA | c.627C>T p.N209= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV100933336; called by muse, mutect2, varscan2
- NGF | c.186C>T p.R62= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs780432648, COSV65686832; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRROS | c.387C>T p.H129= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs764718562, COSV60748754; called by muse, mutect2, varscan2
- OR51I1 | c.639A>G p.S213= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV100971294; called by muse, mutect2, varscan2
- OR5H14 | c.573T>C p.D191= | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as COSV101454172; called by muse, mutect2, varscan2
- POLR3A | c.459A>G p.K153= | Silent (SNP) | VAF 51/106 reads (48%) | catalogued as COSV100965659; called by muse, mutect2, varscan2
- PZP | c.2418C>T p.Y806= | Silent (SNP) | VAF 29/110 reads (26%) | catalogued as rs1464899737, COSV99737871; called by muse, mutect2, varscan2
- SEMA5A | c.2646G>T p.G882= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as COSV101228258; called by muse, mutect2, varscan2
- SNCAIP | c.2715A>G p.G905= | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as COSV54410519; called by muse, mutect2, varscan2
- SPEF2 | c.3918C>G p.P1306= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV100607422; called by muse, mutect2, varscan2
- TPO | c.2343T>G p.T781= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as COSV61093329, COSV61099068; called by muse, mutect2, varscan2
- ZIM3 | c.1338T>G p.P446= | Silent (SNP) | VAF 71/128 reads (55%) | catalogued as COSV99518105; called by muse, mutect2, varscan2
- C5orf64 | n.513-44636T>C | Intron (SNP) | VAF 13/30 reads (43%) | catalogued as rs755539606; called by muse, mutect2, varscan2
- PRKN | c.1083+3425A>C | Intron (SNP) | VAF 14/35 reads (40%) | catalogued as COSV100629136; called by muse, mutect2, varscan2
- SDK1 | c.*3364T>C | 3'UTR (SNP) | VAF 54/195 reads (28%) | catalogued as COSV101269365; called by muse, mutect2, varscan2
- SLC35E2A | n.979G>A | RNA (SNP) | VAF 10/47 reads (21%) | catalogued as rs769766710, COSV99870795; called by muse, mutect2, varscan2
